Somatic mutation profile of tumor specimen TCGA-BP-4177-01A (aliquot TCGA-BP-4177-01A-02D-1421-08) from TCGA case TCGA-BP-4177, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 65.6 years (23,955 days).
Specimen TCGA-BP-4177-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 88fb5dd5-160a-4d34-8365-360a1ef1f98e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BP-4177-11A (Solid Tissue Normal), aliquot TCGA-BP-4177-11A-01D-1421-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8e4625f3-9c3d-43cb-9557-d9ecebc3d958

The open-access MAF lists 13 somatic variants for this specimen: 7 protein-altering or splice-affecting, 6 silent.
By variant classification: Missense Mutation 7, Silent 6.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AHDC1 | c.166G>A p.A56T | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs766999202, COSV55940763; called by muse, mutect2, varscan2
- ASAH2 | c.1031C>G p.A344G | Missense Mutation (SNP) | VAF 57/173 reads (33%) | SIFT tolerated (0.17); PolyPhen benign (0.058); catalogued as rs752003480, COSV61484073; called by muse, mutect2, varscan2
- CATSPERB | c.1320T>G p.F440L | Missense Mutation (SNP) | VAF 78/290 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV56430866; called by muse, mutect2, varscan2
- CSK | c.132C>A p.D44E | Missense Mutation (SNP) | VAF 10/82 reads (12%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.867); catalogued as COSV54974947; called by muse, mutect2, varscan2
- KAT6A | c.2219G>T p.R740L | Missense Mutation (SNP) | VAF 32/115 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); catalogued as COSV55909496, COSV99705244; called by muse, mutect2, varscan2
- POLR2E | c.73G>A p.G25S | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.724); catalogued as COSV53124788; called by muse, mutect2
- YIPF7 | c.466T>C p.F156L | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); catalogued as COSV60657500; called by muse, mutect2, varscan2
- CCDC114 | c.705G>A p.Q235= | Silent (SNP) | VAF 67/201 reads (33%) | catalogued as COSV59557720; called by muse, mutect2, varscan2
- GPAT3 | c.324A>G p.V108= | Silent (SNP) | VAF 105/326 reads (32%) | catalogued as COSV52358516; called by muse, mutect2, varscan2
- HEATR5B | c.5385G>A p.K1795= | Silent (SNP) | VAF 58/196 reads (30%) | catalogued as COSV51856036; called by muse, mutect2, varscan2
- OCLN | c.1218C>G p.G406= | Silent (SNP) | VAF 31/254 reads (12%) | catalogued as COSV62285737, COSV62286166; called by muse, mutect2, varscan2
- TACR3 | c.1014C>T p.Y338= | Silent (SNP) | VAF 68/235 reads (29%) | catalogued as COSV59205363; called by muse, mutect2, varscan2
- TXNDC11 | c.369G>T p.R123= | Silent (SNP) | VAF 36/139 reads (26%) | catalogued as COSV51601318; called by muse, mutect2, varscan2
